Gene-level copy-number profile of specimen HCM-BROD-0120-C15-85A from HCMI case HCM-BROD-0120-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2; Age at diagnosis: 46.6 years (17,010 days).
Specimen HCM-BROD-0120-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 91e8ef62-1894-45ed-b37f-bb138456536c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0120-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,243 have no estimate.
https://portal.gdc.cancer.gov/files/7cdee056-d49e-4f11-aaac-8d889f1a976a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 478; copy number 2: 5,317; copy number 3: 12,385; copy number 4: 24,029; copy number 5: 7,110; copy number 6: 5,736; copy number 7: 1,837; copy number 8: 682; copy number 9: 364; copy number 10: 154; copy number 11: 54; copy number 12: 13; copy number 13: 41; copy number 14: 25; copy number 15: 73; copy number 16: 2; copy number 17: 6; copy number 19: 5; copy number 23: 33; copy number 25: 5; copy number 26: 8; copy number 28: 7; copy number 31: 1; copy number 33: 12; copy number 38: 1; copy number 39: 1; copy number 43: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 806 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:60,750,575–62,078,335, 7 genes, copy number 9 (within-gene range 7–9): LINC02496, AC105420.1, MIR548AG1, LINC02271, ADGRL3, RPL17P19, AC020741.1.
- chr4:63,350,114–63,351,472, 1 gene, copy number 10: LARP1BP1.
- chr7:78,939,850–78,940,895, 1 gene, copy number 9 (within-gene range 8–9): MAGI2-AS1.
- chr7:79,768,028–80,246,225, 4 genes, copy number 9: GNAI1, RNU6-849P, RPL10P11, RN7SL869P.
- chr7:108,470,417–112,206,407, 28 genes, copy number 9–25: PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1, AC002386.1, AC073071.1, AC073387.1, AC073387.2, EIF3IP1, RPL3P8, AC073114.1, AC073114.2, IMMP2L, AC073326.1, LRRN3, AC003989.2, AC003989.1, DOCK4, AC003077.1, DOCK4-AS1, RNA5SP237, AC003080.1.
- chr8:67,952,046–69,923,047, 25 genes, copy number 9: PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P.
- chr8:69,987,415–69,987,697, 1 gene, copy number 9: SUMO2P20.
- chr10:57,513,157–57,513,425, 1 gene, copy number 9: AL731534.1.
- chr10:58,512,872–64,826,579, 64 genes, copy number 10–15 (broad region; genes not listed).
- chr11:101,451,564–103,479,863, 52 genes, copy number 9: TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1.
- chr11:103,907,189–104,164,379, 3 genes, copy number 9: PDGFD, AP003043.1, DDI1.
- chr11:104,682,383–104,919,073, 4 genes, copy number 9: AP001485.1, AP002004.1, CASP12, CASP4LP.
- chr11:118,994,334–122,619,274, 88 genes, copy number 9–11 (broad region; genes not listed).
- chr11:123,358,428–123,627,774, 1 gene, copy number 9 (within-gene range 8–9): GRAMD1B.
- chr11:123,597,946–123,599,452, 1 gene, copy number 9: SF3A3P2.
- chr11:123,723,914–123,754,545, 2 genes, copy number 9: ZNF202, OR6X1.
- chr11:123,805,335–126,102,413, 100 genes, copy number 9 (broad region; genes not listed).
- chr12:12,310–1,936,574, 45 genes, copy number 9: DDX11L8, WASH8P, FAM138D, IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940.
- chr12:50,504,985–51,515,763, 35 genes, copy number 13–17: DIP2B, RNU6-769P, RNU6-238P, Y_RNA, AC013244.1, ATF1, AC013244.2, RN7SL519P, TMPRSS12, AC013244.3, METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2, RNU6-87P, RNU6-1273P, LETMD1, CSRNP2, TFCP2, RPL35AP29, PHBP19, Y_RNA, RNU6-199P, POU6F1, AC139768.1, DAZAP2, SMAGP, BIN2, CELA1, GALNT6, SLC4A8, AC107031.1.
- chr12:66,347,431–70,637,440, 85 genes, copy number 10–15 (within-gene range 3–18) (broad region; genes not listed).
- chr13:18,467,172–18,611,675, 5 genes, copy number 9: ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388.
- chr13:25,371,974–26,053,385, 7 genes, copy number 9 (within-gene range 9–10): ATP8A2, RNU6-78P, AL157366.1, RN7SL741P, RNY1P3, SHISA2, LINC00415.
- chr17:28,861,072–30,702,775, 88 genes, copy number 10–19 (broad region; genes not listed).
- chr17:34,927,859–35,191,702, 18 genes, copy number 26–33: CCT6B, AC022903.2, ZNF830, LIG3, RFFL, AC004223.3, AC004223.4, AC004223.2, AC004223.1, RAD51D, RNU6-840P, Vault, FNDC8, NLE1, UNC45B, AC022916.4, AC022916.2, AC022916.3.
- chr17:37,642,947–37,684,252, 1 gene, copy number 43 (within-gene range 6–43): AC243571.2.
- chr17:37,686,431–38,735,605, 30 genes, copy number 10–39 (within-gene range 4–39): HNF1B, AC243571.1, YWHAEP7, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA, MRPL45, GPR179, SOCS7, ARHGAP23, AC244153.1, SRCIN1, AC006449.1, EPOP, MIR4734, AC006449.6, AC006449.2, MLLT6, AC006449.3, MIR4726, AC006449.7, CISD3, RNA5SP440.
- chr18:21,650,901–23,437,961, 41 genes, copy number 13–23: ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1.
- chr18:23,503,470–27,247,188, 67 genes, copy number 9–10 (broad region; genes not listed).
- chr18:33,578,219–33,751,195, 1 gene, copy number 10: ASXL3.

Autosomal genes at a single copy (total copy number 1): 478. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
